Somatic mutation profile of tumor specimen TCGA-R5-A7ZI-01A (aliquot TCGA-R5-A7ZI-01A-11D-A34U-08) from TCGA case TCGA-R5-A7ZI, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 44.9 years (16,396 days).
Specimen TCGA-R5-A7ZI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4048c42-e671-45cd-b744-9d372eb7993e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R5-A7ZI-10A (Blood Derived Normal), aliquot TCGA-R5-A7ZI-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab14f1d7-71ab-4bbc-ac57-cb0eee36da2b

The open-access MAF lists 1,001 somatic variants for this specimen: 756 protein-altering or splice-affecting, 224 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 507, Silent 224, Frame Shift Del 152, Nonsense Mutation 31, Frame Shift Ins 29, Splice Site 16, In Frame Del 12, RNA 8, Splice Region 6, Intron 5, 5'Flank 3, 3'Flank 2.

Variants (750 of 1,001; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- DLD | c.633del p.V212Ffs*12 | Frame Shift Del (DEL) | VAF 31/82 reads (38%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MYH7 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs377491278, CM1410892; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- OTC | c.663+2T>C p.X221_splice | Splice Site (SNP) | VAF 30/96 reads (31%) | catalogued as rs72558427, CS971836, COSV99234054; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAT | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100528605; called by muse, mutect2, varscan2
- AARS2 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs749519355, COSV55117085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs777439793; called by mutect2, pindel, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC3 | c.709_711del p.E237del | In Frame Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs751858011; called by pindel, varscan2
- ABCC9 | c.2545C>A p.H849N | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99685265; called by muse, mutect2, varscan2
- AC008397.2 | c.2096G>A p.G699D | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV99441490; called by muse, mutect2, varscan2
- AC013489.1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs761569485, COSV99183844; called by muse, mutect2, varscan2
- ACKR1 | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as COSV100929516; called by muse, mutect2, varscan2
- ACP5 | c.802A>C p.K268Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99520276; called by muse, mutect2, varscan2
- ACRBP | c.848A>T p.E283V | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV99976044; called by muse, mutect2, varscan2
- ACSL3 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as rs376738660; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 48/126 reads (38%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM22 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs558399747, COSV55971830; called by muse, mutect2, varscan2
- ADAM29 | c.2003del p.P668Lfs*37 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as COSV63662452; called by mutect2, pindel, varscan2
- ADAMTS4 | c.2318G>A p.G773D | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1384372265, COSV100917721; called by muse, mutect2
- ADAMTS4 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1445185625, COSV100917490, COSV63487589; called by muse, mutect2, varscan2
- ADAT3 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100280186; called by muse, mutect2, varscan2
- ADGRG4 | c.8590A>G p.M2864V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99795041; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | catalogued as rs761350619; called by mutect2, varscan2
- AF196969.1 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.062); catalogued as COSV99339320; called by muse, mutect2, varscan2
- AFF1 | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100320369; called by muse, mutect2, varscan2
- AFF3 | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.23); catalogued as COSV100418485; called by muse, mutect2, varscan2
- AFF4 | c.317G>T p.S106I | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as COSV99534787; called by muse, mutect2, varscan2
- AHNAK2 | c.14363A>C p.E4788A | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.188); catalogued as COSV100316754; called by muse, mutect2, varscan2
- AHNAK2 | c.9123G>T p.Q3041H | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as COSV100316755; called by muse, mutect2, varscan2
- AHR | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 43/137 reads (31%) | catalogued as COSV99619521; called by muse, mutect2, varscan2
- AK5 | c.1054G>C p.D352H (on ENST00000354567 / NM_174858.3; = p.D326H on NM_012093.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV100642528; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 24/131 reads (18%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | catalogued as COSV62339755; called by mutect2, varscan2
- ALKBH6 | c.72C>A p.Y24* (on ENST00000252984 / NM_001297701.2; = p.Y52* on NM_032878.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV99430970; called by muse, mutect2, varscan2
- AMZ1 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs999550677, COSV56689037; called by muse, mutect2, varscan2
- ANGPTL4 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100035062; called by mutect2, varscan2
- ANK3 | c.10909C>T p.H3637Y | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99779280; called by muse, mutect2, varscan2
- ANKH | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV52477457; called by muse, mutect2
- ANKS3 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100423022; called by muse, varscan2
- ANKS6 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776208967, COSV100782253; called by muse, mutect2, varscan2
- ANO6 | c.1354A>G p.I452V | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV100262822; called by muse, mutect2, varscan2
- ANTXR1 | c.1029G>A p.W343* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100362234; called by muse, mutect2, varscan2
- ARHGAP35 | c.4315C>T p.R1439W | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs986522562, COSV68331276; called by muse, mutect2, varscan2
- ARHGAP36 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV99357498; called by muse, mutect2, varscan2
- ARHGEF10 | c.945G>T p.K315N (on ENST00000398564; = p.K290N on NM_014629.4) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100034294; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1391481708, COSV57599514, COSV57605252; called by muse, mutect2, varscan2
- ARL10 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100055361, COSV53798818; called by muse, mutect2, varscan2
- ARMC3 | c.668A>T p.E223V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99957786; called by muse, mutect2, varscan2
- ARNT | c.413A>G p.H138R | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100591050; called by muse, mutect2
- ARVCF | c.905A>G p.E302G | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99599111; called by muse, mutect2, varscan2
- ASCC3 | c.2654C>T p.P885L | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100225514; called by muse, mutect2, varscan2
- ASTN2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.727); catalogued as rs554132287, COSV57804953; called by mutect2, varscan2
- ASZ1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs766060538, COSV52912490; called by muse, mutect2, varscan2
- ATAT1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.819); catalogued as rs779896670, COSV99527851; called by mutect2, varscan2
- ATF6B | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as rs759543441, COSV64351563; called by muse, mutect2, varscan2
- ATM | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99588902; called by muse, mutect2, varscan2
- ATM | c.5645G>A p.R1882Q | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs587782236, COSV99588903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1B1 | c.64_66del p.K22del | In Frame Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs1255481007; called by pindel, varscan2
- ATP2B3 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs782034545, COSV54856756; called by muse, varscan2
- ATR | c.7430A>G p.H2477R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100637963; called by muse, mutect2, varscan2
- AVL9 | c.793T>C p.S265P | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1255830141, COSV100594556; called by muse, mutect2, varscan2
- BARD1 | c.1788del p.K596Nfs*9 | Frame Shift Del (DEL) | VAF 23/139 reads (17%) | catalogued as COSV53612208; called by mutect2, pindel, varscan2
- BCHE | c.626dup p.N209Kfs*10 | Frame Shift Ins (INS) | VAF 14/91 reads (15%) | catalogued as rs769660002; called by mutect2, varscan2
- BCL6 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 54/339 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1218233420, COSV51651047; called by muse, mutect2, varscan2
- BCL7C | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs760033767, COSV99288557; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 25/112 reads (22%) | catalogued as rs768244116; called by mutect2, pindel
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs752427670; called by mutect2, varscan2
- BHLHE22 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100417684; called by muse, mutect2, varscan2
- BIN3 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99373931; called by muse, mutect2
- BIRC6 | c.3689G>T p.R1230I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV101428084; called by muse, mutect2, varscan2
- BPNT1 | c.791A>T p.D264V | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100435618; called by muse, mutect2, varscan2
- BRPF1 | c.1560-2A>G p.X520_splice | Splice Site (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100121179; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BRWD3 | c.1719G>C p.L573F | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100955879; called by muse, mutect2, varscan2
- BSPRY | c.975G>T p.W325C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99444863; called by muse, mutect2, varscan2
- BSX | c.541G>T p.G181W | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV100545182, COSV58006252; called by muse, mutect2, varscan2
- C1QTNF1 | c.406del p.A136Pfs*30 | Frame Shift Del (DEL) | VAF 11/87 reads (13%) | catalogued as COSV59261462; called by mutect2, pindel, varscan2
- C3AR1 | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99368369; called by muse, mutect2, varscan2
- C9orf131 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.063); catalogued as COSV100398006; called by muse, mutect2, varscan2
- CACNA1S | c.4415G>A p.R1472H | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201463541, COSV100754861; called by muse, mutect2, varscan2
- CACNB1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs779856110, COSV59997944; called by muse, mutect2, varscan2
- CAMK1D | c.475T>A p.S159T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101123612; called by muse, mutect2, varscan2
- CBWD3 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 44/480 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.649); catalogued as COSV100730994; called by muse, varscan2
- CC2D2A | c.4674G>T p.R1558S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV100377811; called by muse, mutect2, varscan2
- CCDC14 | c.2072G>A p.G691D (on ENST00000488653; = p.G643D on NM_022757.5) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100113083; called by muse, mutect2, varscan2
- CCDC180 | c.500dup p.L167Ffs*6 | Frame Shift Ins (INS) | VAF 16/79 reads (20%) | catalogued as rs577900246; called by mutect2, varscan2
- CCDC33 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs201603982, COSV100350564; called by muse, mutect2, varscan2
- CCKBR | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1323044843, COSV100582861; called by muse, mutect2
- CCN1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs774059615, COSV71704306; called by muse, mutect2, varscan2
- CCR7 | c.424A>G p.S142G | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV99878642, COSV99878891; called by muse, mutect2, varscan2
- CD151 | c.279C>T p.Y93= | Splice Region (SNP) | VAF 6/38 reads (16%) | catalogued as rs1410161906, COSV100431744; called by muse, mutect2, varscan2
- CDRT4 | c.268T>C p.F90L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100381523; called by muse, mutect2, varscan2
- CEL | c.619del p.D207Tfs*41 (on ENST00000673714; = p.D204Tfs*41 on NM_001807.6) | Frame Shift Del (DEL) | VAF 30/174 reads (17%) | catalogued as rs754393686, COSV60827096; called by mutect2, pindel, varscan2
- CELSR3 | c.3581G>A p.R1194H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs758290257, COSV99373140; called by muse, mutect2, varscan2
- CENPE | c.365A>C p.D122A | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV99477513; called by muse, mutect2, varscan2
- CEP104 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as rs778850368, COSV65517349; called by muse, mutect2, varscan2
- CEP120 | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as COSV100070977; called by muse, mutect2, varscan2
- CERS2 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1486553086, COSV99644270; called by muse, mutect2
- CETP | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs144949752; called by muse, mutect2, varscan2
- CFAP43 | c.494T>C p.M165T | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99530570; called by muse, mutect2, varscan2
- CFAP53 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 58/375 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs751078877, COSV68353065; called by muse, mutect2, varscan2
- CFAP54 | c.7532G>A p.R2511Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs115230871, COSV100733068; called by muse, mutect2, varscan2
- CFAP58 | c.1501T>C p.Y501H | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs142218964; called by muse, mutect2, varscan2
- CFAP91 | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202065099, COSV56339615; called by muse, mutect2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 23/118 reads (19%) | catalogued as rs1561489348; called by mutect2, varscan2
- CHD4 | c.2774C>T p.A925V (on ENST00000357008 / NM_001363606.2; = p.A938V on NM_001273.5) | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100537691; called by muse, mutect2, varscan2
- CHFR | c.872C>T p.A291V (on ENST00000432561 / NM_001161345.1; = p.A250V on NM_018223.2) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1277312621, COSV99905178; called by muse, mutect2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 22/123 reads (18%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRNA10 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99167129; called by muse, mutect2
- CHTOP | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.045); catalogued as rs377148288; called by muse, mutect2, varscan2
- CKAP5 | c.4442G>A p.R1481H | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as rs1209391506, COSV56373503; called by muse, mutect2
- CKMT2 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs200838735, COSV54172794; called by muse, mutect2, varscan2
- CLCN4 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 90/327 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV101073741; called by muse, mutect2, varscan2
- CNTN6 | c.109T>A p.F37I | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as COSV100610453; called by muse, mutect2, varscan2
- CNTNAP5 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV101443307; called by muse, mutect2, varscan2
- COG2 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as rs933159291, COSV64188619; called by muse, mutect2, varscan2
- COL10A1 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778701685, COSV99684160; called by muse, mutect2, varscan2
- COL3A1 | c.1762-1G>T p.X588_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | catalogued as COSV58591126, COSV58594445; called by muse, varscan2
- COL6A6 | c.2858C>G p.P953R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100650116; called by muse, mutect2, varscan2
- COL9A3 | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292275075, COSV100673349; called by muse, mutect2, varscan2
- COL9A3 | c.1750G>A p.G584S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780489761, COSV100102365, COSV58984351; called by muse, mutect2, varscan2
- COQ2 | c.893A>G p.D298G | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100269945; called by muse, mutect2
- CPM | c.357A>G p.I119M | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs755115719, COSV100615003; called by muse, mutect2, varscan2
- CPN1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs760356142, COSV64942879; called by muse, mutect2, varscan2
- CPNE2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs765014242, COSV51963816; called by muse, mutect2, varscan2
- CPOX | c.842G>A p.C281Y | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV99939072; called by muse, mutect2, varscan2
- CRIM1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV54875914; called by muse, mutect2, varscan2
- CRYBG3 | c.7072T>A p.L2358I | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV99476825; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 24/143 reads (17%) | catalogued as rs762650691; called by pindel, varscan2
- CSMD3 | c.5353G>T p.G1785* (on ENST00000297405 / NM_001363185.1; = p.G1681* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 15/221 reads (7%) | catalogued as COSV52266923, COSV52351481; called by muse, mutect2
- CTRC | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs770675516, COSV101036321; ClinVar: uncertain significance; called by muse, varscan2
- CYBB | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs781986436, COSV101059725; called by muse, mutect2, varscan2
- CYBRD1 | c.553T>C p.S185P | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100361258; called by muse, mutect2, varscan2
- CYP2A7 | c.345C>T p.G115= | Splice Region (SNP) | VAF 3/15 reads (20%) | catalogued as rs779969613, COSV99393918; called by muse, mutect2
- CYP3A5 | c.1346T>C p.M449T | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs141469784; called by muse, mutect2, varscan2
- DCAF12L2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as COSV100758530; called by muse, mutect2, varscan2
- DCAF13 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs755309968, COSV52571478; called by muse, mutect2, varscan2
- DCLK3 | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69364766; called by muse, mutect2, varscan2
- DDIAS | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100231111; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX53 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60069795; called by muse, mutect2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs772416332; called by mutect2, varscan2
- DEDD | c.457T>C p.C153R | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100919062; called by muse, mutect2, varscan2
- DEFA4 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.171); catalogued as rs772958227, COSV99857694; called by muse, mutect2, varscan2
- DEFB136 | c.213A>C p.Q71H | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs1211327025, COSV101198611; called by muse, mutect2, varscan2
- DGAT1 | c.691_693del p.K231del | In Frame Del (DEL) | VAF 13/86 reads (15%) | catalogued as rs782733856; called by pindel, varscan2
- DGAT2 | c.406T>G p.F136V | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); catalogued as COSV99929652; called by muse, mutect2, varscan2
- DHX33 | c.1024G>T p.G342W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99834298; called by muse, varscan2
- DIP2C | c.4616G>A p.R1539Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773007279, COSV55159441; called by muse, mutect2, varscan2
- DLGAP2 | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV70093241; called by muse, mutect2, varscan2
- DMD | c.8828C>T p.T2943M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751810893, COSV100626663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNA2 | c.3074C>A p.P1025H | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64429498; called by muse, mutect2, varscan2
- DNAH10 | c.811A>G p.N271D (on ENST00000409039; = p.N210D on NM_207437.3) | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as COSV101292145; called by muse, mutect2, varscan2
- DNAH3 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV99766207; called by muse, mutect2, varscan2
- DNAH7 | c.9250A>G p.K3084E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100414592; called by muse, mutect2, varscan2
- DNAI4 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs144510256; called by muse, mutect2, varscan2
- DNAJB8 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs199505596, COSV59878428; called by muse, mutect2, varscan2
- DNAJC13 | c.5200G>A p.A1734T | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs538703638, COSV99607004; called by muse, mutect2, varscan2
- DNAJC13 | c.6080T>C p.L2027S | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99607006; called by muse, mutect2, varscan2
- DNAJC17 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1157118485, COSV99549079; called by muse, mutect2, varscan2
- DNM2 | c.2377dup p.L793Pfs*31 (on ENST00000355667 / NM_001005360.3; = p.L789Pfs*31 on NM_004945.3) | Frame Shift Ins (INS) | VAF 13/94 reads (14%) | catalogued as rs764391392, COSV53034926; called by mutect2, varscan2
- DNMBP | c.2448G>T p.Q816H | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100143457; called by muse, mutect2, varscan2
- DOCK2 | c.1817T>C p.V606A | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99911375; called by muse, mutect2, varscan2
- DOCK6 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs751675629, COSV53913274; called by muse, mutect2, varscan2
- DOP1A | c.6563G>A p.S2188N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1359400755, COSV99381516; called by muse, mutect2, varscan2
- DPEP1 | c.622del p.V208Sfs*13 | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | catalogued as COSV99878704; called by mutect2, pindel, varscan2
- DPEP2 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1452721094, COSV52056283; called by muse, mutect2, varscan2
- DUOXA1 | c.950A>G p.Q317R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.253); catalogued as rs754407796, COSV99973020; called by muse, mutect2, varscan2
- DUSP3 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99871433; called by muse, mutect2, varscan2
- DUSP6 | c.800A>C p.N267T | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54378001, COSV99684008; called by muse, mutect2, varscan2
- DYNC1H1 | c.483del p.F161Lfs*52 | Frame Shift Del (DEL) | VAF 22/137 reads (16%) | catalogued as rs1566996283; called by mutect2, pindel, varscan2
- DYNC1H1 | c.2873T>C p.V958A | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100794707; called by muse, mutect2, varscan2
- DYNC1H1 | c.13654A>G p.T4552A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV64136529; called by muse, mutect2, varscan2
- EBF1 | c.1411G>A p.V471M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); catalogued as rs1156761801, COSV100565435, COSV100565559; called by muse, mutect2, varscan2
- EEFSEC | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs145560504; called by muse, mutect2, varscan2
- EIF1AD | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770575012; called by muse, mutect2
- EIF3B | c.1085dup p.E363Rfs*18 | Frame Shift Ins (INS) | VAF 46/138 reads (33%) | catalogued as rs764010445; called by mutect2, varscan2
- EIF3E | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.206); catalogued as COSV99623006; called by muse, mutect2, varscan2
- EIF4EBP1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs767454211, COSV58774023; called by muse, varscan2
- EIF4G3 | c.1689dup p.V564Sfs*12 | Frame Shift Ins (INS) | VAF 24/194 reads (12%) | catalogued as rs1558140642; called by mutect2, varscan2
- EPB41L2 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs140419333; called by muse, mutect2, varscan2
- EPG5 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV99956936; called by muse, mutect2, varscan2
- EPHX1 | c.1040+2T>C p.X347_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99688831; called by mutect2, varscan2
- ERBIN | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99396479; called by muse, mutect2, varscan2
- ESF1 | c.1891C>A p.P631T | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs933009780, COSV52522321, COSV99176313; called by muse, mutect2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | catalogued as rs775950025; called by mutect2, varscan2
- FAM120A | c.3113C>T p.S1038L | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs761701846, COSV52901015; called by muse, mutect2, varscan2
- FAM160B1 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs868860537, COSV100985377; called by muse, mutect2, varscan2
- FAM161B | c.1775C>T p.A592V (on ENST00000651776; = p.A529V on NM_152445.3) | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs150485088; called by muse, mutect2, varscan2
- FAM47C | c.1666T>A p.S556T | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.494); catalogued as COSV100792419; called by muse, mutect2, varscan2
- FAM71B | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780542907, COSV57227920; called by muse, mutect2, varscan2
- FARP1 | c.2690G>A p.R897H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.8); catalogued as rs1157099768, COSV60333628; called by muse, mutect2, varscan2
- FARP2 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99884342; called by muse, mutect2, varscan2
- FAT3 | c.12281C>T p.T4094M | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as rs1188622335, COSV99964295; called by muse, mutect2, varscan2
- FBXO11 | c.2260G>A p.A754T (on ENST00000403359 / NM_001190274.2; = p.A670T on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.803); catalogued as COSV99315583; called by muse, mutect2, varscan2
- FBXO36 | c.378+2T>C p.X126_splice | Splice Site (SNP) | VAF 34/188 reads (18%) | catalogued as rs754369086, COSV99391504; called by muse, mutect2, varscan2
- FECH | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34134387, COSV50492251; called by muse, mutect2, varscan2
- FGFR2 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CD061416, COSV60642940; called by muse, mutect2, varscan2
- FJX1 | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV100502642; called by muse, mutect2, varscan2
- FKBP10 | c.1087G>A p.V363M | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782552532, COSV54057832; called by muse, mutect2, varscan2
- FLG2 | c.5467G>A p.G1823R | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1159144028, COSV101165760; called by muse, mutect2, varscan2
- FLNC | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 65/214 reads (30%) | catalogued as COSV100367867; called by muse, mutect2, varscan2
- FLT1 | c.3495T>C p.D1165= | Splice Region (SNP) | VAF 19/96 reads (20%) | catalogued as rs1467757503, COSV99151254; called by muse, mutect2, varscan2
- FLT3 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99608166; called by muse, mutect2, varscan2
- FOXF1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99296442; called by muse, mutect2, varscan2
- FRAS1 | c.2923C>T p.Q975* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | catalogued as COSV99350271; called by muse, mutect2, varscan2
- FREM2 | c.6169+1G>A p.X2057_splice | Splice Site (SNP) | VAF 17/92 reads (18%) | catalogued as COSV99748010; called by muse, mutect2, varscan2
- FRMPD3 | c.4276C>T p.R1426C | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs767491266, COSV52198165; called by muse, mutect2, varscan2
- FRY | c.5935C>T p.Q1979* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100969009; called by muse, mutect2, varscan2
- FZD4 | c.1456T>G p.L486V | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV101536036; called by muse, mutect2, varscan2
- GABBR1 | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.324); catalogued as COSV100589574; called by muse, mutect2, varscan2
- GABBR2 | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs748191490, COSV99409691; called by muse, mutect2, varscan2
- GABRQ | c.59T>G p.L20R | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV100941182; called by muse, mutect2, varscan2
- GABRR3 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs747256149, COSV72084471; called by muse, mutect2, varscan2
- GAL3ST1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100143000; called by muse, mutect2, varscan2
- GALNT10 | c.1007A>G p.D336G | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768613; called by muse, mutect2, varscan2
- GALNT13 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as rs781701306, COSV101222141, COSV67219952; called by muse, mutect2, varscan2
- GASK1B | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); catalogued as COSV99647477; called by muse, mutect2, varscan2
- GBP6 | c.1699_1701del p.K567del | In Frame Del (DEL) | VAF 20/98 reads (20%) | catalogued as rs755314330; called by pindel, varscan2
- GLCE | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs749027018, COSV55945045, COSV55947400; called by muse, mutect2, varscan2
- GLI2 | c.3805A>G p.T1269A (on ENST00000361492 / NM_001374353.1; = p.T1286A on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV100082827; called by muse, mutect2, varscan2
- GLI3 | c.3551C>T p.A1184V | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV101229799; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs749150409; called by mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs370114090; called by mutect2, varscan2
- GPAT4 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101213955; called by muse, mutect2, varscan2
- GPATCH2L | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV55047758; called by muse, mutect2, varscan2
- GPR119 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as rs765431695, COSV52275007; called by muse, mutect2
- GPR25 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100421709; called by muse, mutect2, varscan2
- GPR31 | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV100834115, COSV64761123; called by muse, mutect2, varscan2
- GPR45 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.823); catalogued as rs1173529372, COSV99306864; called by muse, mutect2, varscan2
- GPR6 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV51572850; called by muse, mutect2, varscan2
- GPR63 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.46); catalogued as COSV100013242; called by muse, mutect2, varscan2
- GPRC5A | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201358570, COSV99185543; called by muse, mutect2, varscan2
- GRHL1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1268249357, COSV100257690; called by muse, mutect2, varscan2
- GRIN2B | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101662992; called by muse, mutect2, varscan2
- GRM7 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100736072; called by muse, mutect2, varscan2
- GTF3C3 | c.2538+1G>A p.X846_splice | Splice Site (SNP) | VAF 5/60 reads (8%) | catalogued as COSV99826612; called by muse, mutect2
- GTPBP3 | c.170C>G p.A57G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV99344283; called by muse, mutect2, varscan2
- GUCY2C | c.589A>T p.T197S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99663465; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as COSV54945907; called by mutect2, varscan2
- H1-3 | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99768697; called by muse, mutect2, varscan2
- HAPLN4 | c.705del p.T236Pfs*43 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as COSV52270379; called by mutect2, pindel
- HAUS4 | c.996G>T p.E332D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.826); catalogued as COSV99246834; called by muse, mutect2, varscan2
- HECW1 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.038); catalogued as COSV67838374; called by muse, mutect2, varscan2
- HERC1 | c.6680A>G p.D2227G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.419); catalogued as COSV101496485; called by muse, mutect2
- HERC5 | c.418del p.I140* | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs770854785; called by mutect2, varscan2
- HIRA | c.22T>C p.W8R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54275487, COSV99600108; called by muse, mutect2, varscan2
- HLA-A | c.681C>A p.C227* | Nonsense Mutation (SNP) | VAF 33/224 reads (15%) | catalogued as COSV100954337; called by muse, varscan2
- HNRNPAB | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.935); catalogued as COSV100359314; called by muse, mutect2, varscan2
- HSPA2 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV55968519; called by muse, mutect2, varscan2
- HVCN1 | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99657148; called by muse, mutect2
- IDH3G | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV99473072; called by muse, mutect2, varscan2
- IFT172 | c.3989G>A p.R1330H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.472); catalogued as rs202236985; called by muse, mutect2, varscan2
- IGF2BP1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs779507141, COSV51729787; called by muse, mutect2, varscan2
- IGFLR1 | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs1323039921, COSV53073399; called by muse, mutect2, varscan2
- IGHM | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as rs1566818456; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.233G>C p.S78T | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as rs768143755; called by muse, mutect2, varscan2
- IGSF9 | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as COSV100829610; called by muse, mutect2, varscan2
- IL36RN | c.320T>A p.L107H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.339); catalogued as COSV100697239; called by muse, mutect2, varscan2
- IL4I1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs1364045269, COSV62009322; called by muse, varscan2
- INO80 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV99054981; called by muse, mutect2, varscan2
- INTS4 | c.2165T>A p.I722K | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV100489924; called by muse, mutect2, varscan2
- IPO8 | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV99805055; called by muse, mutect2, varscan2
- IQCN | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758650340, COSV101148526; called by muse, mutect2, varscan2
- IRAG1 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV101351053; called by muse, mutect2, varscan2
- IREB2 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51926400, COSV99359236; called by muse, mutect2
- IRS1 | c.2431A>G p.T811A | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100524310; called by muse, mutect2, varscan2
- ITGA2B | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99288716; called by muse, mutect2, varscan2
- ITGA5 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as rs770030872, COSV99516523; called by muse, mutect2, varscan2
- ITGA7 | c.1021C>A p.L341M (on ENST00000555728; = p.L297M on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV99145051; called by muse, mutect2, varscan2
- ITGB4 | c.1580G>A p.G527D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV52321944; called by muse, mutect2, varscan2
- ITSN2 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs775911766, COSV100743128; called by muse, mutect2, varscan2
- JAG1 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99652675; called by muse, mutect2, varscan2
- JARID2 | c.268T>C p.S90P | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100521643; called by muse, mutect2, varscan2
- KAT5 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100383871; called by muse, mutect2, varscan2
- KCNB2 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73051008; called by muse, mutect2, varscan2
- KCNH8 | c.2352dup p.N785Qfs*3 | Frame Shift Ins (INS) | VAF 16/74 reads (22%) | catalogued as rs760381227; called by mutect2, varscan2
- KCNJ2 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as rs1042485, COSV99696311; called by muse, mutect2, varscan2
- KCTD6 | c.283T>C p.F95L | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100250093; called by muse, mutect2, varscan2
- KDM3A | c.2300A>C p.K767T | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.074); catalogued as COSV100460223; called by muse, mutect2, varscan2
- KDM4D | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | catalogued as rs142280183; called by mutect2, varscan2
- KDM4D | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV100624204, COSV58633888; called by muse, mutect2, varscan2
- KDM5A | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.255); catalogued as rs200720917, COSV66994605; called by muse, mutect2, varscan2
- KDM5B | c.4628G>A p.R1543Q | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.389); catalogued as rs761912360, COSV99350367; called by muse, mutect2, varscan2
- KDM5B | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as rs746793440, COSV52507643, COSV52511361; called by muse, mutect2, varscan2
- KDR | c.4001T>C p.V1334A | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV55770597, COSV99817222; called by muse, mutect2, varscan2
- KIAA1549L | c.4057T>C p.F1353L (on ENST00000321505; = p.F1650L on NM_012194.3) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1465164933, COSV100381219; called by muse, mutect2, varscan2
- KIF18A | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV99588500; called by muse, mutect2, varscan2
- KIF1A | c.4736G>A p.R1579Q (on ENST00000320389 / NM_001379639.1; = p.R1571Q on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as rs761974755, COSV57505211; ClinVar: uncertain significance; called by muse, mutect2
- KIF9 | c.2035G>A p.D679N (on ENST00000265529 / NM_001377474.1; = p.D614N on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.199); catalogued as rs1407632342, COSV99646570; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KLC3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as rs1302917549, COSV67270388, COSV67270976; called by muse, mutect2, varscan2
- KLHDC7B | c.1306G>A p.A436T (on ENST00000395676; = p.A1077T on NM_138433.5) | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as rs144157815; called by muse, mutect2, varscan2
- KLHL17 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs751447032, COSV100497944; called by muse, mutect2, varscan2
- KLHL34 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV101069903, COSV65278739; called by muse, mutect2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 59/185 reads (32%) | catalogued as rs749194179; called by mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2D | c.231del p.H77Qfs*53 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as COSV56471398, COSV99980400; called by mutect2, pindel, varscan2
- KRT19 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); catalogued as rs541372182, COSV54181733; called by muse, mutect2, varscan2
- KRT75 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.727); catalogued as rs543738510, COSV52871434, COSV52871699; called by muse, mutect2, varscan2
- KRT79 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs750144914, COSV100398384; called by muse, mutect2, varscan2
- LAMA2 | c.396+2T>C p.X132_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as COSV101370315; called by muse, mutect2, varscan2
- LAMA4 | c.1357+1G>A p.X453_splice (on ENST00000230538 / NM_001105206.3; = p.X446_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/111 reads (16%) | catalogued as rs1057524730, COSV100038044, COSV57892098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMC1 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751220972; called by muse, mutect2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LILRA4 | c.1214T>G p.L405R | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99393020; called by muse, varscan2
- LIMA1 | c.2100A>T p.Q700H | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as COSV100372362; called by muse, mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 22/126 reads (17%) | catalogued as rs765287063; called by mutect2, varscan2
- LMOD1 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1467030597, COSV100939120, COSV66172485; called by mutect2, varscan2
- LNPEP | c.1337A>G p.D446G | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.464); catalogued as COSV99183508; called by muse, mutect2, varscan2
- LPCAT2 | c.1599G>T p.K533N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100044675; called by muse, mutect2, varscan2
- LRP1B | c.2447G>T p.R816L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV67213075, COSV67290810; called by muse, mutect2, varscan2
- LRRC28 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.085); catalogued as COSV100113461; called by muse, mutect2, varscan2
- LRRC31 | c.34G>T p.G12* | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | catalogued as COSV99246550; called by muse, mutect2, varscan2
- LRRC7 | c.3508A>G p.N1170D (on ENST00000651989 / NM_001370785.2; = p.N1137D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.389); catalogued as COSV99225727; called by muse, mutect2, varscan2
- LTBP3 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147206443; called by muse, mutect2, varscan2
- LUZP1 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752769715, COSV56500948; called by muse, mutect2, varscan2
- LUZP1 | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100034725; called by muse, mutect2, varscan2
- MAG | c.1585A>G p.I529V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100727702; called by muse, mutect2, varscan2
- MAGEB6 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100983704; called by muse, mutect2, varscan2
- MAGEB6B | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs764042835; called by muse, mutect2, varscan2
- MANSC1 | c.14del p.G5Efs*5 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | catalogued as rs1341236086; called by mutect2, pindel, varscan2
- MAP3K10 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs916960455, COSV53423184; called by muse, mutect2
- MAPK4 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.364); catalogued as rs761132815, COSV101245301; called by muse, mutect2, varscan2
- MARK3 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1001396009, COSV99358084; called by muse, mutect2, varscan2
- MASTL | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as rs367614863; called by muse, mutect2, varscan2
- MB21D2 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as rs367797905; called by muse, mutect2, varscan2
- MC5R | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV61254595; called by muse, mutect2, varscan2
- MDH1B | c.853G>T p.G285W | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.775); catalogued as rs745503724, COSV100982162; called by muse, mutect2, varscan2
- MECP2 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 76/564 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.662); catalogued as rs185957513, COSV57654203; ClinVar: benign; called by muse, mutect2, varscan2
- MED12 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61336851; called by muse, mutect2, varscan2
- MED14 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100247409; called by muse, mutect2, varscan2
- MEOX2 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV100012020; called by muse, mutect2, varscan2
- MEST | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs551376794, COSV99784043; called by muse, mutect2, varscan2
- MFN1 | c.1969A>G p.I657V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs1055746839, COSV99764342; called by muse, mutect2, varscan2
- MICALL2 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs1428751796, COSV52516024; called by muse, mutect2, varscan2
- MICU2 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101212425; called by muse, mutect2, varscan2
- MICU3 | c.535+2T>C p.X179_splice | Splice Site (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100536232; called by muse, mutect2, varscan2
- MICU3 | c.803del p.N268Mfs*47 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs199759760; called by mutect2, varscan2
- MIDEAS | c.1310T>C p.V437A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV99678755; called by muse, mutect2, varscan2
- MIPEP | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs769570896, COSV101193061; called by muse, mutect2, varscan2
- MITD1 | c.232T>C p.Y78H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99175551; called by muse, mutect2, varscan2
- MKS1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs559966703, COSV100439546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLH1 | c.307-1G>A p.X103_splice | Splice Site (SNP) | VAF 11/56 reads (20%) | catalogued as CS033127, COSV51619999, COSV99212388; called by muse, mutect2, varscan2
- MMP3 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as rs377547395; called by muse, mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 5/21 reads (24%) | catalogued as rs777649506, COSV53202254; called by mutect2, varscan2
- MOV10L1 | c.3346T>C p.F1116L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as COSV99433440; called by muse, mutect2, varscan2
- MPP3 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV101263315; called by muse, mutect2, varscan2
- MRGPRX3 | c.173G>T p.R58M | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101283514; called by muse, mutect2, varscan2
- MROH2B | c.4114del p.I1372Sfs*5 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | catalogued as rs756600463; called by mutect2, varscan2
- MROH2B | c.731_732del p.K244Rfs*3 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs1345868427; called by mutect2, pindel, varscan2
- MSH6 | c.3503C>T p.T1168I | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV52288082; called by muse, mutect2, varscan2
- MTR | c.3136C>A p.L1046M | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV100855310; called by muse, mutect2, varscan2
- MTREX | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57927837; called by muse, mutect2, varscan2
- MUC15 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as COSV99846323; called by muse, mutect2
- MUC2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs779507902; called by muse, mutect2, varscan2
- MUC5B | c.8425C>A p.L2809M | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.488); catalogued as COSV101500213; called by muse, mutect2, varscan2
- MUC6 | c.4567A>G p.T1523A | Missense Mutation (SNP) | VAF 48/336 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.067); catalogued as COSV101424494; called by muse, varscan2
- MXRA5 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs745871213, COSV54224205; called by muse, mutect2, varscan2
- MYB | c.1009A>G p.R337G | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs772410551, COSV100214717; called by muse, mutect2, varscan2
- MYG1 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.773); catalogued as rs965236600, COSV99266895; called by muse, mutect2, varscan2
- MYLK | c.2657C>T p.A886V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs140989388, COSV60612823; called by muse, mutect2, varscan2
- MYO1H | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 106/310 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs368271068; called by muse, mutect2, varscan2
- NAT1 | c.575T>G p.F192C | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100306487; called by muse, mutect2, varscan2
- NAV2 | c.1249G>A p.A417T (on ENST00000396087 / NM_001244963.2; = p.A394T on NM_145117.5) | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100585402; called by muse, mutect2, varscan2
- NCAPD3 | c.2071A>T p.I691F | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV101599344; called by muse, varscan2
- NCOA7 | c.1927G>T p.D643Y | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99996812; called by muse, mutect2, varscan2
- NCOR2 | c.2620C>G p.P874A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100657125; called by muse, mutect2, varscan2
- NELL2 | c.1677C>A p.C559* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as COSV100419252, COSV61583875; called by muse, mutect2, varscan2
- NFASC | c.2045C>A p.P682H (on ENST00000339876 / NM_001378329.1; = p.P678H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100363397; called by muse, mutect2, varscan2
- NFIB | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.175); catalogued as COSV101101249; called by muse, mutect2
- NKD1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.573); catalogued as rs369647847; called by muse, mutect2, varscan2
- NKRF | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV100441526; called by muse, mutect2, varscan2
- NKX3-2 | c.932A>G p.Y311C | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV101219867; called by muse, mutect2
- NLRC5 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99346861; called by muse, mutect2, varscan2
- NLRP13 | c.107T>C p.L36S | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100738136; called by muse, mutect2, varscan2
- NOL11 | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1245848160, COSV53522621; called by muse, mutect2, varscan2
- NOS1 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100500346; called by muse, mutect2, varscan2
- NOS3 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs376007167; called by muse, mutect2, varscan2
- NOTCH4 | c.5288A>G p.Q1763R | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100900575; called by muse, mutect2, varscan2
- NPHP1 | c.857C>A p.T286N | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1187622609, COSV100337944; called by muse, mutect2, varscan2
- NPHP4 | c.2444C>T p.S815L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs202165848; called by muse, mutect2, varscan2
- NPR2 | c.693G>T p.E231D | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100709416; called by muse, mutect2, varscan2
- NR0B1 | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100973490; called by muse, mutect2, varscan2
- NR4A2 | c.1337T>C p.L446P | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100277061; called by muse, mutect2, varscan2
- NRDE2 | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100583375; called by muse, mutect2, varscan2
- NRF1 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774042493, COSV99781685; called by muse, mutect2, varscan2
- NRP2 | c.2249A>G p.Q750R | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55925929, COSV99783948; called by muse, mutect2, varscan2
- NSUN7 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV100349043; called by muse, mutect2, varscan2
- NT5C1A | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs752949958, COSV52496265; called by muse, mutect2, varscan2
- NTMT1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1386164465, COSV99475674; called by muse, mutect2, varscan2
- NUP214 | c.3019G>A p.E1007K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs767288782, COSV63911514; called by muse, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 22/90 reads (24%) | catalogued as rs780417788; called by mutect2, varscan2
- ONECUT2 | c.330G>T p.M110I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV101529769; called by muse, mutect2, varscan2
- OR10C1 | c.10A>C p.S4R (on ENST00000622521; = p.S2R on NM_013941.3) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV101010816; called by muse, mutect2
- OR11H6 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1014922358, COSV100209760; called by muse, mutect2, varscan2
- OR13H1 | c.882del p.D295Mfs*6 | Frame Shift Del (DEL) | VAF 15/152 reads (10%) | catalogued as rs766808182, COSV100088244; called by mutect2, pindel
- OR14I1 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs761639634, COSV61200667; called by muse, mutect2, varscan2
- OR1N2 | c.772C>A p.L258I | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV101031369; called by muse, mutect2, varscan2
- OR4C13 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV101634155, COSV73648744; called by muse, mutect2, varscan2
- OR5M11 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99074550; called by muse, mutect2
- OR5M3 | c.797T>A p.V266E | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100392419; called by muse, mutect2, varscan2
- OSBPL5 | c.1634G>A p.G545D | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55146763; called by muse, mutect2
- OTOGL | c.2377T>G p.F793V (on ENST00000547103; = p.F784V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as COSV101509129; called by muse, mutect2
- OTOP2 | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs1404444647, COSV100508854; called by muse, mutect2, varscan2
- PACSIN3 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs567457200, COSV100096183; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1240A>G p.K414E (on ENST00000259318 / NM_001136562.3; = p.K645E on NM_007203.5) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV99395016; called by muse, mutect2, varscan2
- PAN2 | c.2654T>C p.V885A (on ENST00000425394 / NM_001127460.3; = p.V881A on NM_014871.5) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.143); catalogued as COSV99228221; called by muse, mutect2, varscan2
- PARD3 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs766656338, COSV100400835, COSV60745900; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PC | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100852151; called by muse, mutect2, varscan2
- PCBD1 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV54738820; called by muse, mutect2, varscan2
- PCDH15 | c.3185C>T p.A1062V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100218365, COSV57284012; called by muse, mutect2, varscan2
- PCDH17 | c.3235C>A p.L1079M | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.387); catalogued as COSV100931544; called by muse, mutect2, varscan2
- PCDHA12 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV56497769; called by muse, mutect2, varscan2
- PCDHA12 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.087); catalogued as rs782552942, COSV99165576; called by muse, mutect2, varscan2
- PCDHA8 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs564409198, COSV100969336; called by muse, mutect2, varscan2
- PCLO | c.8570T>C p.L2857P | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV100430192; called by muse, mutect2, varscan2
- PCNT | c.7574G>A p.R2525H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs940897400, COSV100855319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCOLCE2 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.03); catalogued as COSV99930536; called by muse, mutect2, varscan2
- PCSK5 | c.2543del p.P848Qfs*15 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | catalogued as COSV100950231; called by mutect2, pindel*
- PDE1B | c.1565del p.P522Hfs*25 | Frame Shift Del (DEL) | VAF 33/176 reads (19%) | catalogued as rs780236743; called by mutect2, varscan2
- PDE4B | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100305698, COSV58468886; called by muse, mutect2, varscan2
- PDE6A | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774005137, COSV54926442; called by muse, mutect2, varscan2
- PDLIM1 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs1282378335, COSV100267719; called by muse, mutect2, varscan2
- PDLIM1 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); catalogued as COSV100267721; called by muse, mutect2, varscan2
- PEX16 | c.640G>T p.G214W | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99572142; called by muse, mutect2, varscan2
- PHEX | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 103/367 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65074803; called by muse, mutect2, varscan2
- PHF10 | c.1448del p.P483Qfs*? | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | catalogued as rs754137375; called by mutect2, pindel, varscan2
- PHF6 | c.834+3C>T | Splice Region (SNP) | VAF 23/176 reads (13%) | catalogued as COSV100136356; called by muse, mutect2, varscan2
- PIK3C2G | c.3971A>G p.Y1324C (on ENST00000676171; = p.Y1283C on NM_004570.5) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333356873, COSV99850769; called by muse, mutect2, varscan2
- PIK3C3 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1289206436, COSV100010689; called by muse, mutect2, varscan2
- PIWIL2 | c.2828C>A p.P943H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100769325; called by muse, mutect2, varscan2
- PKHD1 | c.8887G>A p.V2963I | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs749794881, COSV100582295, COSV100582364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKMYT1 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs747195888, COSV99233983; called by muse, mutect2, varscan2
- PKN2 | c.1483A>T p.I495F | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60132516; called by muse, mutect2
- PLA2G12B | c.37A>G p.S13G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs369202731; called by mutect2, varscan2
- PLEC | c.6206C>T p.A2069V (on ENST00000322810 / NM_201380.4; = p.A1959V on NM_000445.5) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.106); catalogued as rs201624086, COSV100512609; called by muse, mutect2, varscan2
- PLEKHA2 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101173381; called by muse, mutect2, varscan2
- PLEKHA7 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755067711, COSV100850190; called by muse, mutect2, varscan2
- PLPPR2 | c.620G>A p.C207Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99264346; called by muse, mutect2, varscan2
- PLXNA4 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs867833410, COSV58107902; called by muse, mutect2, varscan2
- PLXNB1 | c.3977C>A p.P1326Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.56); catalogued as COSV99602617; called by muse, mutect2, varscan2
- PNN | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as rs754286118, COSV99397119; called by muse, mutect2, varscan2
- POLE | c.2485A>G p.M829V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs762395135, COSV100265948; ClinVar: uncertain significance; called by mutect2, varscan2
- POM121 | c.1261C>T p.R421* (on ENST00000434423; = p.R156* on NM_172020.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/294 reads (7%) | catalogued as rs782682880, COSV57511210; called by muse, mutect2
- POMK | c.43del p.R15Efs*11 | Frame Shift Del (DEL) | VAF 27/117 reads (23%) | catalogued as rs749980792, COSV100505682; called by mutect2, pindel, varscan2
- POR | c.516G>A p.A172= | Splice Region (SNP) | VAF 19/130 reads (15%) | catalogued as rs782798260, COSV101203551; called by muse, mutect2, varscan2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 15/116 reads (13%) | catalogued as rs775130624; called by mutect2, varscan2
- PPM1A | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57787460; called by muse, mutect2, varscan2
- PRDM11 | c.380del p.P127Rfs*40 (on ENST00000530656 / NM_001359633.1; = p.P93Rfs*40 on NM_001256695.1) | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | catalogued as COSV55440445; called by mutect2, varscan2
- PRF1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.324); catalogued as COSV100942572; called by muse, mutect2, varscan2
- PRKAG1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV60293294; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | catalogued as rs753236928; called by mutect2, varscan2
- PRR14 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs144165240; called by mutect2, varscan2
- PSEN1 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99997724; called by muse, mutect2, varscan2
- PSMD6 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99895963; called by muse, mutect2, varscan2
- PTBP1 | c.1266G>T p.E422D (on ENST00000349038 / NM_031991.4; = p.E448D on NM_002819.5) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100608509; called by muse, mutect2
- PTPN3 | c.2570C>T p.T857I | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs370374314; called by muse, mutect2, varscan2
- PTPN3 | c.2021del p.N674Tfs*28 | Frame Shift Del (DEL) | VAF 33/121 reads (27%) | catalogued as COSV52711823; called by mutect2, pindel, varscan2
- PTPRM | c.3575C>T p.T1192M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59869692; called by muse, mutect2, varscan2
- PTPRZ1 | c.2318C>A p.P773H | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101099893, COSV66448444; called by muse, mutect2, varscan2
- QDPR | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs755564399, COSV55551108; called by muse, mutect2, varscan2
- R3HDM2 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as COSV100715039; called by muse, mutect2, varscan2
- RAB11FIP3 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751750453, COSV99240089; called by muse, mutect2, varscan2
- RAB17 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99221274; called by muse, mutect2, varscan2
- RABGAP1L | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99269163; called by muse, mutect2, varscan2
- RALGDS | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs776063928, COSV64426305; called by muse, mutect2
- RANBP6 | c.2918del p.N973Mfs*12 | Frame Shift Del (DEL) | VAF 20/127 reads (16%) | catalogued as rs746880803; called by mutect2, varscan2
- RANBP9 | c.1263A>C p.E421D | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV99163513; called by muse, mutect2, varscan2
- RASL12 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs138898900, COSV99584856; called by muse, mutect2, varscan2
- RBM24 | c.625G>T p.A209S (on ENST00000379052 / NM_001143942.2; = p.A164S on NM_153020.2) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.978); catalogued as COSV100552931; called by muse, mutect2, varscan2
- RBM25 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV56199821; called by muse, mutect2, varscan2
- RFX4 | c.973T>C p.S325P (on ENST00000392842 / NM_213594.3; = p.S231P on NM_032491.6) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99985644; called by muse, mutect2, varscan2
- RGL2 | c.608del p.G203Afs*49 | Frame Shift Del (DEL) | VAF 27/166 reads (16%) | catalogued as rs762949421; called by mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 32/78 reads (41%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RHOBTB2 | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs571326568; called by muse, mutect2
- RHOT2 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99553077; called by muse, mutect2, varscan2
- RICTOR | c.1136A>G p.H379R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99704687; called by muse, mutect2, varscan2
- RILPL1 | c.575A>C p.E192A | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV100526004; called by muse, mutect2, varscan2
- RNF123 | c.2653C>T p.H885Y | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as rs753289504, COSV57539090; called by muse, mutect2, varscan2
- ROBO4 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.498); catalogued as rs772735983, COSV100127449; called by muse, mutect2, varscan2
- RPS6KA1 | c.1104del p.S369Afs*18 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | catalogued as rs745561139; called by mutect2, pindel, varscan2
- RPS6KA6 | c.327del p.A110Pfs*3 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | catalogued as rs756096568; called by mutect2, pindel, varscan2
- RTL3 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100329662; called by muse, mutect2, varscan2
- RTN3 | c.3064A>G p.K1022E (on ENST00000377819 / NM_001265589.2; = p.K226E on NM_006054.4) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100380028; called by muse, mutect2, varscan2
- RTN4RL1 | c.455A>C p.Q152P | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100486511; called by muse, mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 22/110 reads (20%) | catalogued as rs756606313; called by mutect2, varscan2
- RUBCNL | c.1829C>T p.T610M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs200512455; called by mutect2, varscan2
- RXRA | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100709221; called by muse, mutect2, varscan2
- RXRB | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.12); catalogued as COSV100807653; called by muse, mutect2, varscan2
- SAMD4A | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV99200608; called by muse, mutect2, varscan2
- SAP130 | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as rs762355437, COSV99384469; called by muse, mutect2, varscan2
- SCAF8 | c.1719G>A p.W573* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | catalogued as COSV100781299, COSV100781322; called by muse, mutect2
- SCAMP2 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1190295854, COSV51510560; called by muse, mutect2, varscan2
- SCIN | c.2024A>C p.K675T (on ENST00000297029 / NM_001112706.3; = p.K428T on NM_033128.3) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as COSV99764678; called by muse, mutect2, varscan2
- SDHAF4 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as rs755569057, COSV100976339; called by muse, mutect2, varscan2
- SDK1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs746427735, COSV67367712; called by muse, mutect2, varscan2
- SEC61A2 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs1262026166, COSV53652393; called by muse, mutect2, varscan2
- SECISBP2L | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1050509072, COSV55934474; called by muse, mutect2, varscan2
- SEPSECS | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs546059546, COSV100258769; called by muse, mutect2, varscan2
- SETD6 | c.535_537del p.K179del (on ENST00000219315 / NM_001160305.4; = p.K155del on NM_024860.3) | In Frame Del (DEL) | VAF 16/96 reads (17%) | catalogued as rs1179845666; called by mutect2, pindel, varscan2
- SFR1 | c.212G>A p.R71H (on ENST00000369727 / NM_001002759.1; = p.R58H on NM_145247.4) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as rs763971940, COSV100312324; called by muse, varscan2
- SGIP1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775124239, COSV52779339; called by muse, varscan2
- SH2B2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV60826338; called by muse, mutect2, varscan2
- SH3BP4 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as COSV100749081; called by muse, mutect2, varscan2
- SH3KBP1 | c.702A>T p.E234D | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV101114584; called by muse, mutect2, varscan2
- SIK2 | c.2723A>G p.D908G | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100232048; called by muse, mutect2, varscan2
- SIPA1 | c.2912C>A p.P971H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV100425781; called by muse, mutect2, varscan2
- SLC1A2 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1360598399, COSV99554270; called by muse, mutect2, varscan2
- SLC1A3 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV99467328; called by muse, mutect2, varscan2
- SLC22A1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs138657404; called by muse, mutect2, varscan2
- SLC22A18 | c.993C>G p.F331L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100388748; called by muse, mutect2
- SLC24A5 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100165197; called by muse, mutect2, varscan2
- SLC25A41 | c.100del p.Q34Nfs*44 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs745556777; called by mutect2, pindel, varscan2
- SLC25A51 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs748466748, COSV99643308; called by muse, mutect2, varscan2
- SLC2A4 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99142684; called by muse, mutect2, varscan2
- SLC35F2 | c.886C>A p.L296M | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99758566; called by muse, mutect2, varscan2
- SLC44A4 | c.8del p.G3Efs*44 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | catalogued as rs760348287; called by mutect2, pindel, varscan2
- SLC4A10 | c.386G>C p.G129A | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV99763276; called by muse, mutect2, varscan2
- SLIT3 | c.1426A>G p.S476G | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100266507; called by muse, mutect2, varscan2
- SMG5 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as rs146907826; called by muse, mutect2, varscan2
- SMG6 | c.2455C>T p.Q819* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99557999; called by muse, mutect2, varscan2
- SNX20 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs375118669; called by muse, mutect2
- SNX27 | c.1339A>G p.S447G | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs1424977950, COSV100919002; called by muse, mutect2, varscan2
- SOAT1 | c.1501G>C p.V501L | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV100858919; called by muse, mutect2, varscan2
- SORBS2 | c.3130del p.E1044Nfs*65 (on ENST00000284776 / NM_021069.5; = p.E610Nfs*65 on NM_003603.6) | Frame Shift Del (DEL) | VAF 24/164 reads (15%) | catalogued as rs772549791, COSV52996321; called by mutect2, pindel, varscan2
- SORCS1 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1318641243, COSV99545002; called by muse, mutect2, varscan2
- SORL1 | c.3920A>C p.D1307A | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99493390; called by muse, mutect2
- SP140 | c.1825+2T>C p.X609_splice | Splice Site (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100613596; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 10/89 reads (11%) | catalogued as rs746109620; called by mutect2, varscan2
- SP2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763819687, COSV100947163; called by muse, mutect2, varscan2
- SPACA3 | c.5T>C p.V2A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99284148; called by muse, mutect2
- SPATA16 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV100651073; called by muse, mutect2, varscan2
- SPOCK3 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as COSV62740903; called by muse, mutect2, varscan2
- SPTA1 | c.2971C>T p.R991C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs565611676, COSV100934677, COSV63757307; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SRP68 | c.1271T>C p.L424P | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100326040; called by muse, mutect2, varscan2
- ST18 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as rs766226164, COSV99389038; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAG2 | c.3217A>G p.K1073E | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.506); catalogued as COSV99492896; called by muse, mutect2, varscan2
- STAT4 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100636006; called by muse, mutect2, varscan2
- SYMPK | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs754446044, COSV99841563; called by muse, mutect2, varscan2
- SYNE1 | c.15541C>A p.L5181M (on ENST00000367255 / NM_182961.4; = p.L5110M on NM_033071.3) | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV99558958; called by muse, mutect2, varscan2
- SYNE1 | c.14394del p.E4799Rfs*6 (on ENST00000367255 / NM_182961.4; = p.E4728Rfs*6 on NM_033071.3) | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as COSV54895423; called by mutect2, pindel, varscan2
- SYNE1 | c.12313A>G p.K4105E (on ENST00000367255 / NM_182961.4; = p.K4034E on NM_033071.3) | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV99558968; called by muse, mutect2, varscan2
- SYNE1 | c.11974G>T p.G3992C (on ENST00000367255 / NM_182961.4; = p.G3921C on NM_033071.3) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV99558974; called by muse, mutect2, varscan2
- SYNE1 | c.11219C>T p.T3740I (on ENST00000367255 / NM_182961.4; = p.T3725I on NM_033071.3) | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1434298372, COSV55058697, COSV99558976; called by muse, mutect2, varscan2
- SYNE2 | c.17471G>T p.S5824I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV100647286; called by muse, mutect2, varscan2
- SYT3 | c.286del p.L96Cfs*5 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs765263349; called by mutect2, pindel, varscan2
- SYVN1 | c.1579G>A p.V527M (on ENST00000377190 / NM_172230.3; = p.V526M on NM_032431.3) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as rs146285421; called by muse, mutect2
- TAF1 | c.1877del p.K626Rfs*4 (on ENST00000373790 / NM_138923.4; = p.K647Rfs*4 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | catalogued as rs745516519; called by mutect2, varscan2
- TAP2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376467259; called by muse, mutect2, varscan2
- TASOR2 | c.6037A>T p.I2013F | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100050261; called by muse, mutect2, varscan2
- TBC1D2 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs368438612; called by muse, mutect2, varscan2
- TBL1X | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); catalogued as COSV99482371; called by muse, mutect2, varscan2
- TCF20 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV59493801; called by muse, mutect2, varscan2
- TCHH | c.2772A>C p.Q924H | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV100914960; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 28/208 reads (13%) | catalogued as rs763321097; called by mutect2, varscan2
- TENT4A | c.2209A>G p.M737V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as COSV100048785; called by muse, mutect2, varscan2
- TESPA1 | c.1434C>A p.S478R (on ENST00000316577 / NM_001098815.3; = p.S340R on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV100345103; called by muse, mutect2, varscan2
- TESPA1 | c.890G>A p.R297Q (on ENST00000316577 / NM_001098815.3; = p.R159Q on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as rs371019313, COSV57258461; called by muse, mutect2, varscan2
- TGDS | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99725047; called by muse, mutect2, varscan2
- THSD1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs201109452; called by muse, mutect2, varscan2
- THSD4 | c.2614A>C p.T872P | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV99965075; called by muse, mutect2, varscan2
- TLN1 | c.4567C>T p.R1523C | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1424218976, COSV100148276, COSV59206739; called by muse, mutect2, varscan2
- TM4SF5 | c.446del p.P149Lfs*8 | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | catalogued as rs1567708962; called by mutect2, pindel, varscan2
- TMC1 | c.1214A>G p.E405G | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs969922326, COSV52767299; called by muse, mutect2, varscan2
- TMEM117 | c.1021T>A p.Y341N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV99862306; called by muse, mutect2, varscan2
- TMOD1 | c.926del p.N309Tfs*24 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | catalogued as rs1484682870; called by mutect2, pindel, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs770800449; called by mutect2, varscan2
- TNFAIP8L2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs777732715, COSV64423257; called by muse, mutect2, varscan2
- TNIP1 | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100161247; called by muse, mutect2, varscan2
- TOX | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100789271; called by muse, mutect2, varscan2
- TOX2 | c.1429A>G p.S477G (on ENST00000358131 / NM_001098798.2; = p.S453G on NM_032883.3) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV100363675; called by muse, mutect2, varscan2
- TRAM1L1 | c.36del p.V13Ffs*128 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs753182240; called by mutect2, pindel, varscan2
- TRIM16 | c.1469G>A p.G490D | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV100371814; called by mutect2, varscan2
- TRIM23 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs750308452, COSV99139921; called by muse, mutect2, varscan2
- TRIM29 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 48/282 reads (17%) | catalogued as rs1273863461, COSV59280042; called by muse, mutect2, varscan2
- TRIM68 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs777719012, COSV56167604; called by muse, mutect2, varscan2
- TRIP12 | c.1842+2T>A p.X614_splice | Splice Site (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99389825; called by muse, mutect2, varscan2
- TRIP6 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as rs201241149, COSV99566602, COSV99566658; called by muse, mutect2, varscan2
- TRMT10C | c.423del p.V142* | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as COSV59305963; called by mutect2, pindel, varscan2
- TRRAP | c.8752G>A p.E2918K (on ENST00000359863 / NM_001244580.1; = p.E2900K on NM_003496.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100722295; called by muse, mutect2
- TSHR | c.1366C>A p.L456M | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991493; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 26/121 reads (21%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL13P | c.149del p.N50Mfs*17 | Frame Shift Del (DEL) | VAF 23/126 reads (18%) | catalogued as rs773117671; called by mutect2, pindel, varscan2
- TTN | c.21613G>A p.V7205I (on ENST00000591111; = p.V6278I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/195 reads (18%) | PolyPhen benign (0.012); catalogued as COSV100603629; called by muse, mutect2, varscan2
- TUBGCP6 | c.5197G>A p.V1733I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs775546712, COSV50617790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TULP2 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55479954; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs760251146; called by mutect2, varscan2
- TWIST1 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99643027; called by muse, mutect2, varscan2
- U2AF1L4 | c.467G>A p.R156H (on ENST00000412391; = p.R117H on NM_001040425.3) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as rs746648207, COSV53075817, COSV53076330; called by muse, mutect2, varscan2
- U2AF2 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100454188; called by muse, mutect2, varscan2
- UBA1 | c.185T>C p.L62S | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100255585; called by muse, mutect2, varscan2
- UBAC1 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65613713; called by muse, mutect2, varscan2
- UBE2Q2 | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as COSV99143224; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754342361, COSV51959111; called by muse, mutect2, varscan2
- ULK1 | c.2779T>C p.C927R | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.697); catalogued as COSV100416686; called by muse, mutect2, varscan2
- USP1 | c.1985del p.N662Mfs*2 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs751218576; ClinVar: not provided; called by mutect2, varscan2
- USP13 | c.1896del p.I633* | Frame Shift Del (DEL) | VAF 23/133 reads (17%) | catalogued as rs780272979; called by mutect2, pindel, varscan2
- USP16 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765372408, COSV100537889, COSV57624408; called by muse, mutect2, varscan2
- USP20 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs762740870, COSV100204200; called by muse, mutect2, varscan2
- USP44 | c.1690T>C p.C564R | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.105); catalogued as rs745410068, COSV99311719; called by muse, mutect2, varscan2
- USP8 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs759611314, COSV56168389; called by muse, mutect2, varscan2
- UTP14C | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs747293991, COSV73000684; called by muse, mutect2, varscan2
- VAX1 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99524037; called by muse, mutect2, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 30/184 reads (16%) | catalogued as rs756863093; called by mutect2, varscan2
- VNN2 | c.1182_1184del p.R396del | In Frame Del (DEL) | VAF 25/145 reads (17%) | catalogued as rs763459590; called by mutect2, pindel, varscan2
- VPS13B | c.4232G>A p.R1411H | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.745); catalogued as COSV62132609; called by muse, mutect2, varscan2
- VPS13C | c.8804A>T p.N2935I (on ENST00000644861 / NM_020821.3; = p.N2892I on NM_017684.5) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV99827959; called by muse, mutect2, varscan2
- VPS50 | c.2208G>T p.L736F | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100004694, COSV59921889; called by muse, mutect2, varscan2
- WASHC4 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765881333, COSV59891504; called by muse, mutect2, varscan2
- WBP11 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99660618; called by muse, mutect2, varscan2
- WDR72 | c.1601G>A p.C534Y | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100854337; called by muse, mutect2, varscan2
- WFIKKN2 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs931183800, COSV100259800; called by muse, mutect2, varscan2
- WIZ | c.4454G>A p.R1485H (on ENST00000673675 / NM_001371589.1; = p.R390H on NM_021241.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1370470768, COSV99652956; called by muse, mutect2
- WIZ | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as rs61732027, COSV99652959; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | catalogued as rs771899177; called by mutect2, pindel, varscan2
- XIRP1 | c.1034A>G p.Q345R | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs1004209790, COSV100453508; called by muse, mutect2, varscan2
- XPNPEP3 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs748610440, COSV100846670; called by muse, mutect2, varscan2
- YARS1 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as rs767579114, COSV65113864; called by muse, mutect2, varscan2
- YIF1B | c.445C>T p.R149C (on ENST00000339413 / NM_001039673.3; = p.R134C on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779345895, COSV100007862; called by muse, mutect2, varscan2
- YJU2 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99508271; called by muse, mutect2, varscan2
- ZC3H12A | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66103917; called by muse, mutect2, varscan2
- ZC3H18 | c.2406del p.Q804Sfs*15 | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | catalogued as rs750724166; called by mutect2, pindel, varscan2
- ZC3H4 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99452095; called by muse, mutect2
- ZDHHC23 | c.154T>C p.C52R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100362095; called by muse, mutect2, varscan2
- ZDHHC23 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs370624022; called by muse, mutect2, varscan2
- ZFP36L1 | c.812del p.G271Vfs*36 | Frame Shift Del (DEL) | VAF 18/129 reads (14%) | catalogued as rs1421733622; called by mutect2, pindel, varscan2
- ZFPM2 | c.1924C>A p.H642N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as COSV101023125; called by muse, mutect2
- ZMYM1 | c.1517C>A p.T506N | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as rs1170660100, COSV100720941, COSV63251733; called by muse, mutect2, varscan2
- ZMYND19 | c.236del p.G79Afs*14 | Frame Shift Del (DEL) | VAF 16/122 reads (13%) | catalogued as rs753541275; called by mutect2, pindel, varscan2
- ZNF107 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1562847388, COSV100788302; called by muse, mutect2, varscan2
- ZNF236 | c.3771G>T p.E1257D | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV99469886; called by muse, mutect2, varscan2
- ZNF251 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs373010939; called by muse, mutect2, varscan2
- ZNF264 | c.1313A>C p.H438P | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99567183; called by muse, mutect2, varscan2
- ZNF318 | c.3580C>T p.R1194W | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209398200; called by muse, mutect2, varscan2
- ZNF333 | c.965T>G p.I322S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV52885180, COSV99468985; called by muse, mutect2, varscan2
- ZNF366 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as COSV59216354; called by muse, mutect2, varscan2
- ZNF496 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99665498; called by muse, mutect2, varscan2
- ZNF614 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368436045; called by muse, mutect2, varscan2
- ZNF689 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 29/159 reads (18%) | catalogued as COSV54908489; called by muse, mutect2, varscan2
- ZNF710 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99184115; called by muse, mutect2, varscan2
- ZNF782 | c.1149G>A p.W383* | Nonsense Mutation (SNP) | VAF 78/292 reads (27%) | catalogued as COSV100001305; called by muse, mutect2, varscan2
- ZSCAN5B | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.974); catalogued as rs373469763; called by muse, mutect2, varscan2
- ABCA7 | c.3500del p.T1167Kfs*6 | Frame Shift Del (DEL) | VAF 18/113 reads (16%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.573dup p.G192Wfs*41 | Frame Shift Ins (INS) | VAF 53/159 reads (33%) | called by mutect2, pindel, varscan2
- ACSM3 | c.1645del p.T549Lfs*11 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- ADM | c.335dup p.G113Rfs*18 | Frame Shift Ins (INS) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- AOC2 | c.303del p.K102Rfs*33 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | called by mutect2, varscan2
- AOC3 | c.1318del p.L440Cfs*46 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- ARHGEF15 | c.689del p.G230Afs*106 | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel
- ASPM | c.6854_6855dup p.K2286Sfs*7 | Frame Shift Ins (INS) | VAF 19/143 reads (13%) | called by mutect2, varscan2
- ATR | c.3112del p.S1038Lfs*12 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, varscan2
- BAHCC1 | c.6333del p.T2112Rfs*16 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- BARD1 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BEX2 | c.305del p.K102Sfs*3 | Frame Shift Del (DEL) | VAF 28/186 reads (15%) | called by mutect2, pindel, varscan2
- BTAF1 | c.215del p.N72Mfs*30 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- CAMK1G | c.221del p.K74Rfs*8 | Frame Shift Del (DEL) | VAF 20/149 reads (13%) | called by mutect2, pindel, varscan2
- CATSPERG | c.3196del p.A1066Pfs*16 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- CCDC38 | c.447del p.A150Qfs*24 | Frame Shift Del (DEL) | VAF 11/87 reads (13%) | called by mutect2, pindel, varscan2
- CCNE1 | c.1163_1165del p.P388del | In Frame Del (DEL) | VAF 6/56 reads (11%) | called by pindel, varscan2
- CCT3 | c.1127_1129del p.L376del | In Frame Del (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- CCT8L2 | c.1654del p.I552Sfs*4 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | called by mutect2, varscan2
- CHD1 | c.855del p.G286Efs*34 | Frame Shift Del (DEL) | VAF 17/108 reads (16%) | called by mutect2, pindel, varscan2
- CHRNA5 | c.639del p.F213Lfs*9 | Frame Shift Del (DEL) | VAF 11/91 reads (12%) | called by mutect2, pindel, varscan2
- CIC | c.404del p.P135Qfs*70 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- CNNM1 | c.179del p.G60Afs*174 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- CNST | c.322del p.I108Ffs*29 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- COL1A2 | c.2348dup p.G784Wfs*41 | Frame Shift Ins (INS) | VAF 14/85 reads (16%) | called by mutect2, pindel, varscan2
- COL3A1 | c.3648del p.F1216Lfs*20 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | called by mutect2, pindel, varscan2
- CTSC | c.315del p.F105Lfs*10 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel, varscan2
- CTSW | c.262del p.V88* | Frame Shift Del (DEL) | VAF 52/224 reads (23%) | called by mutect2, pindel, varscan2
- CWF19L2 | c.1398del p.E467Nfs*22 | Frame Shift Del (DEL) | VAF 21/205 reads (10%) | called by mutect2, pindel, varscan2
- CXXC1 | c.1412_1413+1del p.X471_splice | Splice Site (DEL) | VAF 24/202 reads (12%) | called by pindel, varscan2
- DAPK1 | c.3822del p.Y1275Tfs*31 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel, varscan2
- DBH | c.1439del p.X480_splice | Splice Site (DEL) | VAF 6/60 reads (10%) | called by pindel, varscan2
- DNAH9 | c.3608del p.K1203Rfs*6 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- DSP | c.5673_5674dup p.K1892Rfs*38 | Frame Shift Ins (INS) | VAF 16/80 reads (20%) | called by mutect2, varscan2
- DTWD1 | c.604del p.I202Lfs*4 | Frame Shift Del (DEL) | VAF 17/148 reads (11%) | called by mutect2, pindel, varscan2
- EPHA2 | c.1791dup p.N598Qfs*96 | Frame Shift Ins (INS) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- FAM13C | c.1466dup p.L489Ffs*4 | Frame Shift Ins (INS) | VAF 9/85 reads (11%) | called by mutect2, pindel, varscan2
- FOXJ3 | c.1154dup p.H385Qfs*65 | Frame Shift Ins (INS) | VAF 14/142 reads (10%) | called by mutect2, pindel
- GCN1 | c.7087del p.V2363Cfs*3 | Frame Shift Del (DEL) | VAF 14/95 reads (15%) | called by mutect2, varscan2
- GDF2 | c.281dup p.N94Kfs*7 | Frame Shift Ins (INS) | VAF 20/96 reads (21%) | called by mutect2, pindel, varscan2
- GLB1L | c.1275del p.F425Lfs*19 | Frame Shift Del (DEL) | VAF 19/113 reads (17%) | called by mutect2, pindel, varscan2
- GLB1L2 | c.1836dup p.E613* | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel
- H2AZ2 | c.352_353del p.L118Dfs*40 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by pindel, varscan2
- HERC2 | c.2907del p.E970Kfs*55 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, varscan2
- HFM1 | c.724del p.S242Qfs*12 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- IGLV1-51 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- IL5RA | c.219dup p.E74Rfs*3 | Frame Shift Ins (INS) | VAF 7/66 reads (11%) | called by mutect2, varscan2
- IRF2 | c.500del p.N167Mfs*7 | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | called by mutect2, pindel, varscan2
- JARID2 | c.3216dup p.E1073Rfs*15 | Frame Shift Ins (INS) | VAF 23/127 reads (18%) | called by mutect2, varscan2
- JMJD1C | c.2930del p.N977Mfs*5 | Frame Shift Del (DEL) | VAF 19/125 reads (15%) | called by mutect2, pindel, varscan2
- JMJD7-PLA2G4B | c.1389_1391del p.T464del | In Frame Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- KDM4B | c.1532del p.P511Lfs*8 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- KMT2C | c.12139del p.S4047Vfs*36 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by mutect2, pindel, varscan2
- LNPK | c.888del p.R297Dfs*8 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- LRWD1 | c.865del p.Q289Rfs*35 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- MAP3K4 | c.479dup p.N160Kfs*27 | Frame Shift Ins (INS) | VAF 13/80 reads (16%) | called by mutect2, varscan2
- MRAP | c.488del p.P163Lfs*18 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- MRC1 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MSANTD4 | c.97del p.S33Pfs*10 | Frame Shift Del (DEL) | VAF 17/156 reads (11%) | called by mutect2, pindel, varscan2
- MTERF3 | c.749del p.L250Cfs*2 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- MUC6 | c.1273dup p.Q425Pfs*119 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- MYBL1 | c.1108del p.V370* | Frame Shift Del (DEL) | VAF 32/148 reads (22%) | called by mutect2, pindel, varscan2
- NECTIN1 | c.1311_1312insAAG p.E437_E438insK | In Frame Ins (INS) | VAF 5/34 reads (15%) | called by pindel, varscan2
- NUB1 | c.357del p.D120Ifs*17 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- NUMA1 | c.1090_1092del p.K364del | In Frame Del (DEL) | VAF 28/92 reads (30%) | called by mutect2, pindel, varscan2
- OR13C9 | c.152del p.L51Wfs*32 | Frame Shift Del (DEL) | VAF 20/151 reads (13%) | called by mutect2, pindel, varscan2
- PAX1 | c.343del p.L115Cfs*33 | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | called by mutect2, pindel, varscan2
- PCLO | c.898dup p.S300Kfs*23 | Frame Shift Ins (INS) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- PDS5B | c.1139del p.K380Rfs*14 | Frame Shift Del (DEL) | VAF 40/193 reads (21%) | called by mutect2, pindel, varscan2
- PHF11 | c.127dup p.R43Kfs*13 | Frame Shift Ins (INS) | VAF 17/108 reads (16%) | called by mutect2, pindel, varscan2
- PIK3AP1 | c.2342_2354del p.P781Hfs*26 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel
- PIK3R1 | c.1378dup p.S460Kfs*5 (on ENST00000521381 / NM_181523.3; = p.S190Kfs*5 on NM_181504.4) | Frame Shift Ins (INS) | VAF 15/100 reads (15%) | called by mutect2, pindel, varscan2
- PKN3 | c.1558dup p.Q520Pfs*19 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel
- PLAA | c.720del p.P241Qfs*7 | Frame Shift Del (DEL) | VAF 22/161 reads (14%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- POTEF | c.2182dup p.R728Pfs*54 | Frame Shift Ins (INS) | VAF 11/89 reads (12%) | called by mutect2, varscan2
- PPRC1 | c.3401_3403dup p.A1134dup | In Frame Ins (INS) | VAF 7/46 reads (15%) | called by mutect2, pindel
- PTPRK | c.4205_4207del p.V1402del (on ENST00000368215 / NM_001291984.2; = p.V1403del on NM_002844.4) | In Frame Del (DEL) | VAF 31/149 reads (21%) | called by mutect2, pindel, varscan2
- PWWP2A | c.1352del p.N451Mfs*26 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel, varscan2
- PYROXD1 | c.1430del p.N477Tfs*3 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- QSOX2 | c.885del p.K295Nfs*56 | Frame Shift Del (DEL) | VAF 19/105 reads (18%) | called by mutect2, pindel, varscan2
- RASA1 | c.1432_1435del p.K478Vfs*4 | Frame Shift Del (DEL) | VAF 18/138 reads (13%) | called by mutect2, pindel, varscan2
- RIPK2 | c.1146del p.F382Lfs*2 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | called by mutect2, pindel, varscan2
- RNF19A | c.187del p.R63Efs*5 | Frame Shift Del (DEL) | VAF 57/168 reads (34%) | called by mutect2, pindel, varscan2
- RPS6KA6 | c.1040dup p.K348Qfs*9 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | called by mutect2, pindel
- SENP3 | c.568del p.R190Gfs*11 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- SLC22A12 | c.1339del p.A447Lfs*20 | Frame Shift Del (DEL) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- SSX2 | c.506G>A p.R169H (on ENST00000337502 / NM_175698.2; = p.V218M on NM_003147.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by mutect2, varscan2
- STPG2 | c.620del p.L207Yfs*3 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel
- TCERG1 | c.1342_1344del p.Y448del | In Frame Del (DEL) | VAF 24/164 reads (15%) | called by pindel, varscan2
- TCERG1 | c.1810_1811del p.M604Efs*4 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | called by mutect2, pindel, varscan2
- TENM2 | c.7255del p.L2419* (on ENST00000518659 / NM_001122679.2; = p.L2180* on NM_001080428.3) | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | called by mutect2, pindel, varscan2
- TMC8 | c.1480dup p.L494Pfs*7 | Frame Shift Ins (INS) | VAF 12/83 reads (14%) | called by mutect2, pindel, varscan2
- TMEM127 | c.701del p.P234Lfs*73 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- TOP3A | c.128del p.N43Tfs*16 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- TRRAP | c.11353dup p.T3785Nfs*137 (on ENST00000359863 / NM_001244580.1; = p.T3756Nfs*137 on NM_003496.3) | Frame Shift Ins (INS) | VAF 24/68 reads (35%) | called by mutect2, varscan2
- TTC14 | c.1677del p.K560Sfs*12 | Frame Shift Del (DEL) | VAF 20/140 reads (14%) | called by mutect2, pindel, varscan2
- TTC17 | c.2673del p.K891Nfs*21 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, pindel, varscan2
- VPS4B | c.592del p.S198Qfs*12 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | called by mutect2, pindel, varscan2
- WAPL | c.1435del p.R479Efs*46 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- WDFY3 | c.483del p.F161Lfs*19 | Frame Shift Del (DEL) | VAF 28/75 reads (37%) | called by mutect2, pindel, varscan2
- WDR13 | c.143del p.P48Qfs*8 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, varscan2
251 further variants in this file (6 protein-altering or splice-affecting, 224 silent, 21 other) are not listed here.
